CCDI case PBBPPS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/6a1e04e0-eba7-4e28-a24f-e1872edadeb2

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Peritoneum, NOS; Age at diagnosis: 7.1 years (2,590 days).

Biospecimens (3 samples)
- Sample 0DE7CY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE7E7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE7FU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
